Somatic mutation profile of tumor specimen TCGA-HG-A2PA-01A (aliquot TCGA-HG-A2PA-01A-11D-A20U-09) from TCGA case TCGA-HG-A2PA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 38.4 years (14,025 days).
Specimen TCGA-HG-A2PA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26fcf28e-5a97-4fde-8384-94152cc8f996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HG-A2PA-10A (Blood Derived Normal), aliquot TCGA-HG-A2PA-10B-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e81bb51a-4db4-4934-aa05-a4ffd3d4e3bf

The open-access MAF lists 76 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 17, Splice Site 3, Nonstop Mutation 1, Intron 1, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABL1 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.233); catalogued as rs971577563, COSV59323854; called by muse, mutect2
- ADAMTS10 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1477523539, COSV54356831; called by muse, mutect2, varscan2
- ADGRL3 | c.1882C>G p.Q628E (on ENST00000506720 / NM_001322402.2; = p.Q560E on NM_015236.6) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV72229086; called by muse, varscan2
- AKR1E2 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.042); catalogued as COSV53629556; called by mutect2, varscan2
- AMOTL1 | c.1820A>G p.E607G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58564778; called by muse, mutect2, varscan2
- ANO4 | c.2057C>A p.P686H (on ENST00000392977 / NM_001286615.2; = p.P651H on NM_178826.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54583739, COSV54602500; called by muse, varscan2
- ANO7 | c.1483C>T p.R495C (on ENST00000274979; = p.R441C on NM_001370694.2) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); catalogued as rs375780942; called by muse, mutect2, varscan2
- ASTN1 | c.2945T>C p.L982S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62490021; called by muse, mutect2
- CDCP1 | c.1940G>C p.S647T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV56103488; called by muse, mutect2, varscan2
- CDK10 | c.275G>A p.R92H (on ENST00000353379 / NM_052988.5; = p.R21H on NM_052987.4) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs373968493; called by muse, mutect2, varscan2
- CHGB | c.1811T>C p.V604A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV66759471; called by muse, mutect2, varscan2
- COL4A6 | c.2845A>G p.N949D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57858397, COSV57863678; called by muse, mutect2, varscan2
- DMXL2 | c.8327A>G p.Q2776R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51840187; called by muse, mutect2, varscan2
- ELOA2 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55292661, COSV55309690; called by muse, mutect2, varscan2
- ERBB4 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV53498170, COSV53605482; called by muse, mutect2, varscan2
- FER1L6 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV67549581; called by muse, mutect2
- GDF5 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1224976540, COSV65499050; called by muse, mutect2
- GKAP1 | c.197A>G p.Q66R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV64488489; called by muse, mutect2, varscan2
- GKAP1 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.547); catalogued as COSV64488494; called by muse, mutect2, varscan2
- GRIN2A | c.3926G>A p.R1309Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58018306; called by muse, mutect2, varscan2
- GSTA2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV72414506; called by muse, mutect2, varscan2
- HMCN1 | c.8662A>G p.K2888E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as rs745459538, COSV54873288; called by muse, mutect2, varscan2
- HSPG2 | c.8773C>G p.Q2925E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.253); catalogued as COSV65932639, COSV65933676; called by muse, mutect2, varscan2
- HTR1D | c.1134G>T p.*378Yext*14 | Nonstop Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV58447201; called by muse, mutect2, varscan2
- IGSF10 | c.6947G>A p.R2316Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as rs765361967, COSV56367113; called by muse, mutect2, varscan2
- JPT2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50188470, COSV99936097; called by muse, mutect2, varscan2
- KMT2D | c.4721C>T p.P1574L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs1487735574, COSV56407432; called by muse, mutect2, varscan2
- MYH2 | c.5083C>T p.R1695W | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55430817; called by muse, mutect2, varscan2
- NAB2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV55665324; called by muse, mutect2, varscan2
- NAPSA | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs898399448, COSV53796589; called by muse, mutect2, varscan2
- NAV3 | c.3779C>G p.S1260C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.302); catalogued as COSV57059265; called by muse, mutect2, varscan2
- OGT | c.1761G>A p.E587= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as COSV65479187; called by muse, mutect2, varscan2
- OR2C1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.208); catalogued as COSV59239486; called by muse, mutect2, varscan2
- OR5D14 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs200387718, COSV59455236; called by mutect2, varscan2
- OSBPL9 | c.1052-1G>A p.X351_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61865486, COSV61865907; called by muse, mutect2, varscan2
- PDHA2 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54776936, COSV54781887; called by muse, mutect2, varscan2
- PLXDC2 | c.1229G>T p.R410I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV65900284; called by muse, mutect2
- PPIL6 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs763721663, COSV70021581; called by muse, mutect2, varscan2
- PSTPIP2 | c.512A>G p.E171G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV68957358; called by muse, mutect2, varscan2
- PTH2R | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV55913414; called by muse, mutect2, varscan2
- RUNDC1 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs755761147, COSV64511399; called by muse, mutect2
- SCARF1 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs369633804; called by muse, mutect2, varscan2
- SIGLEC1 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV52458043; called by muse, mutect2, varscan2
- STXBP5 | c.2318A>G p.N773S (on ENST00000321680 / NM_001127715.2; = p.N737S on NM_139244.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV51647281; called by muse, mutect2
- SYNDIG1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as rs199777977; called by muse, mutect2, varscan2
- SYNE1 | c.23296C>T p.H7766Y (on ENST00000367255 / NM_182961.4; = p.H7695Y on NM_033071.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs886043037, COSV54896015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM266 | c.420G>C p.W140C | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101189589; called by muse, mutect2, varscan2
- TRIOBP | c.5512G>A p.D1838N (on ENST00000644935 / NM_001039141.3; = p.D125N on NM_007032.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs751638156, COSV58525679; called by muse, mutect2, varscan2
- WRN | c.2270C>G p.T757R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV53295609; called by muse, mutect2, varscan2
- ZFP28 | c.932T>G p.F311C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as COSV56734386; called by muse, mutect2
- ZNF277 | c.25del p.A9Lfs*19 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs1224566916; called by mutect2, pindel, varscan2
- ZRANB2 | c.691T>G p.S231A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs746948520, COSV54670242; called by mutect2, varscan2
- PRAMEF18 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, varscan2
- RFC4 | c.997-1_997del p.X333_splice | Splice Site (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SENP5 | c.2099_2106+11del p.X700_splice | Splice Site (DEL) | VAF 6/33 reads (18%) | called by pindel, varscan2
- ARAP1 | c.3939C>T p.L1313= (on ENST00000393609 / NM_001040118.2; = p.L1068= on NM_015242.4) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100501729, COSV100502081; called by muse, mutect2
- ECI1 | c.684G>A p.P228= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs562082375, COSV100066664; called by muse, mutect2, varscan2
- ERMARD | c.918T>C p.F306= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1333986094, COSV64647499, COSV64648002; called by muse, mutect2
- FBH1 | c.1407G>A p.K469= (on ENST00000362091 / NM_178150.3; = p.K520= on NM_032807.4) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV62981320, COSV62983695; called by muse, mutect2, varscan2
- FLNC | c.4029C>T p.G1343= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs767426611, COSV57949422; called by muse, mutect2, varscan2
- GEMIN6 | c.366C>T p.D122= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs200834111; called by muse, mutect2, varscan2
- GPR3 | c.657C>T p.I219= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1205294540, COSV64994403; called by muse, mutect2, varscan2
- H3C11 | c.177C>T p.T59= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs764233454, COSV100137803; called by muse, mutect2
- HDX | c.399A>G p.A133= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV52972314; called by muse, mutect2, varscan2
- IGF1R | c.2226C>T p.V742= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV51269286; called by muse, mutect2, varscan2
- MAGEB1 | c.603G>A p.L201= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV66775103; called by muse, mutect2, varscan2
- NPC1L1 | c.195G>A p.K65= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV56929156; called by muse, mutect2, varscan2
- PRMT5 | c.39C>T p.R13= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs765654523, COSV53544706; called by muse, mutect2, varscan2
- RANBP17 | c.3058A>C p.R1020= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV66643618; called by muse, mutect2, varscan2
- SHANK3 | c.870T>C p.C290= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs202089750, COSV53182892; called by muse, mutect2, varscan2
- SLC24A3 | c.1320C>T p.T440= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV60110412; called by muse, mutect2, varscan2
- TTN | c.23049C>A p.A7683= (on ENST00000591111; = p.A6756= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV59864078; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-11T>C | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- TMEM80 | chr11:695769 G>C | 5'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as COSV58605552; called by muse, mutect2, varscan2
